Gene-level copy-number profile of tumor specimen TCGA-16-0846-01A from TCGA case TCGA-16-0846, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 85.2 years (31,111 days).
Specimen TCGA-16-0846-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.8851bf6a-af6f-4491-8c33-f606dc3ef91c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-16-0846-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a6ff5d8-9b7a-4d26-89fd-19d2bbd4a79b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,620; copy number 3: 7,726; copy number 4: 32,884; copy number 5: 11,394; copy number 6: 3,016; copy number 7: 1; copy number 8: 61; copy number 9: 12; copy number 10: 33; copy number 11: 4; copy number 13: 3; copy number 32: 8; copy number 35: 7; copy number 42: 2; copy number 43: 18; copy number 61: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-16-0846-01A-01D-0384-01): tumor purity 0.64, ploidy 3.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 118 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:20,728,606–21,948,772, 1 gene, copy number 35 (within-gene range 6–35): KCNIP4.
- chr4:21,304,468–21,719,026, 6 genes, copy number 35: AC110296.1, MIR7978, AC096576.7, AC096576.3, AC096576.1, AC096576.2.
- chr4:21,949,015–22,819,575, 7 genes, copy number 9–42 (within-gene range 5–42): AC096719.1, RNU6-420P, ADGRA3, AC098583.1, AC098583.2, GBA3, CDC42P6.
- chr4:26,163,455–27,025,381, 7 genes, copy number 9 (within-gene range 5–9): RBPJ, CCKAR, TBC1D19, AC107390.1, STIM2, STIM2-AS1, PIMREGP4.
- chr4:33,238,239–34,039,914, 7 genes, copy number 10: AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1.
- chr4:39,698,109–40,377,513, 23 genes, copy number 10: UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP, PDS5A, ELOCP33, RNA5SP159, AC098591.3, PABPC1P1, KRT18P25, AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P.
- chr4:51,843,000–51,919,381, 3 genes, copy number 13: DCUN1D4, DUTP7, AC027271.1.
- chr4:52,252,820–52,551,574, 3 genes, copy number 10 (within-gene range 5–10): AC097522.2, AC097522.1, RNU6-1252P.
- chr4:52,872,982–53,366,066, 1 gene, copy number 32 (within-gene range 4–32): SCFD2.
- chr4:53,265,461–54,976,371, 29 genes, copy number 11–43: RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3.
- chr12:57,693,955–58,244,865, 31 genes, copy number 61: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
